Somatic mutation profile of tumor specimen ALCH-AEL7-TTP1-A (aliquot ALCH-AEL7-TTP1-A-1-0-D-A618-36) from ALCHEMIST case ALCH-AEL7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.3 years (19,110 days).
Specimen ALCH-AEL7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88821369-d84d-4d48-bf3a-338fb4a899da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEL7-NB1-A (Blood Derived Normal), aliquot ALCH-AEL7-NB1-A-2-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4bf1173-ee07-4b24-9473-71fc5a0ae6bb

The open-access MAF lists 55 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 9, Intron 5, 3'UTR 1, Nonsense Mutation 1, 5'Flank 1, Frame Shift Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 1649/1939 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ACACB | c.4855G>A p.G1619S | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs780244896; called by muse, mutect2, varscan2
- BRINP1 | c.2114G>T p.R705L | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs769963438; called by muse, mutect2, varscan2
- CDH12 | c.1794C>G p.I598M | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.055); catalogued as COSV66448258; called by muse, mutect2, varscan2
- CROCC | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100978072; called by muse, mutect2
- DDR1 | c.1299C>G p.I433M | Missense Mutation (SNP) | VAF 83/152 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV61323095; called by muse, mutect2, varscan2
- GALC | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54323602; called by muse, mutect2, varscan2
- GPRC5B | c.683G>C p.R228T | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1448419170; called by muse, mutect2, varscan2
- GRM1 | c.2637G>C p.K879N | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV51109582; called by muse, mutect2, varscan2
- IL4R | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs759552353; called by muse, mutect2, varscan2
- MYOM2 | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as rs1172730058; called by muse, mutect2, varscan2
- MYT1L | c.2569G>T p.E857* | Nonsense Mutation (SNP) | VAF 14/282 reads (5%) | catalogued as COSV67732344; called by muse, mutect2
- NRXN3 | c.1922G>A p.R641Q (on ENST00000335750 / NM_001330195.2; = p.R268Q on NM_004796.6) | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs1005062934, COSV59710942, COSV59820730; called by muse, mutect2
- PCDHB6 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as rs1194664955, COSV50691071; called by muse, mutect2
- POMGNT1 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 26/480 reads (5%) | PolyPhen probably damaging (1); catalogued as rs1553163451; called by muse, mutect2
- RTL1 | c.2467G>A p.V823M | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1018029172, COSV101128241; called by muse, mutect2, varscan2
- SBSN | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 54/289 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1176964331; called by muse, mutect2, varscan2
- SMG8 | c.2220G>C p.Q740H | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56286400; called by muse, mutect2
- ZNF623 | c.163A>G p.R55G | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs777501429; called by muse, mutect2, varscan2
- ZNF831 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs568542313, COSV64043632; called by muse, mutect2, varscan2
- CCDC120 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CHORDC1 | c.893C>G p.T298R | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- DGCR2 | c.847T>G p.F283V | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DMXL1 | c.2452C>A p.P818T | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- DNA2 | c.2621C>A p.A874D | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- FLNA | c.5089G>C p.D1697H (on ENST00000369850 / NM_001110556.2; = p.D1689H on NM_001456.3) | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPSM1 | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRTM1 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCKS | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MEST | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- POTEF | c.2094G>C p.E698D | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RASGEF1A | c.1328C>A p.A443E | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2
- RTL1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.483); called by muse, mutect2
- RTN2 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); called by muse, mutect2
- SLC34A2 | c.758A>T p.H253L | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- THRAP3 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- TP53 | c.608_609delinsC p.V203Afs*44 | Frame Shift Del (DEL) | VAF 48/262 reads (18%) | called by pindel, varscan2*
- ADGRG4 | c.4788C>A p.T1596= | Silent (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- BAZ2A | c.4800G>T p.R1600= | Silent (SNP) | VAF 53/304 reads (17%) | called by muse, mutect2, varscan2
- DAW1 | c.18C>A p.L6= | Silent (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- DUS2 | c.996C>T p.A332= | Silent (SNP) | VAF 30/141 reads (21%) | called by muse, mutect2, varscan2
- ITPRID1 | c.2634G>A p.R878= | Silent (SNP) | VAF 9/184 reads (5%) | catalogued as rs1269184276; called by muse, mutect2
- KPTN | c.768C>T p.F256= | Silent (SNP) | VAF 24/129 reads (19%) | called by muse, mutect2, varscan2
- PLB1 | c.2172C>T p.A724= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as rs1445577575, COSV100215073; called by muse, mutect2, varscan2
- RAB30 | c.69G>A p.T23= | Silent (SNP) | VAF 27/402 reads (7%) | catalogued as rs950487914; called by muse, mutect2
- SPATA2 | c.654G>A p.R218= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915445 G>C | 5'Flank (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- ASXL1 | c.1720-47C>T | Intron (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- GABRG2 | c.1249-1327T>C | Intron (SNP) | VAF 14/125 reads (11%) | catalogued as COSV62721389; called by muse, mutect2, varscan2
- OACYLP | n.1281G>A | RNA (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- PFDN4 | c.-6C>G | 5'UTR (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- POTEG | c.811-1124_811-1123insATTTT | Intron (INS) | VAF 27/218 reads (12%) | called by mutect2, varscan2*
- PRDM2 | c.*50A>T | 3'UTR (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- PRRC2A | c.112+179C>T | Intron (SNP) | VAF 120/202 reads (59%) | catalogued as rs770967264; called by muse, varscan2
- SPATA18 | c.1479+21G>T | Intron (SNP) | VAF 30/194 reads (15%) | called by muse, mutect2, varscan2
